Surgical pathology report (de-identified scan), TCGA case TCGA-32-4211, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-4211-01A (Primary Tumor).

SPECIMEN SOURCE:

1. Right frontal brain tumor
2. Right frontal brain tumor

CLINICAL DIAGNOSIS:

Headaches

GROSS DESCRIPTION:

1. Received fresh for frozen section are two tan-red soft tissues measuring 1.0 x 0.4 x 0.2 cm and 0.8 x 0.4 x 0.3 cm. A smear is performed. Entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

CONSISTENT WITH ASTROCYTOMA, FAVOR ANAPLASTIC.

The tissue submitted for frozen is subsequently submitted for permanent.

2. Received in formalin labeled with the patient's name and "right frontal brain tumor" are multiple tan to tan-red soft tissues aggregating to 2.5 x 1.5 x 0.7 cm. The largest portions are serially sectioned and the specimen is entirely submitted in five cassettes. One third of the tissue is sent to

MICROSCOPIC DESCRIPTION:

- 1,2. Sections demonstrate a markedly hypercellular glial neoplasm composed of pleomorphic cells with variable amounts of cytoplasm. The nuclei are hyperchromatic with irregular nuclear contours and coarse chromatin. Seventeen mitoses are observed per ten high power fields. Microvascular proliferation is identified. Focal necrosis is seen. Focal hemorrhage is also observed.

DIAGNOSIS:

- 1,2. BRAIN TUMOR, RIGHT FRONTAL, BIOPSY AND RESECTION:
- GLIOBLASTOMA.

Source: NCI Genomic Data Commons file bc8940a7-f331-4770-ba5d-142a3e6ea31d (TCGA-32-4211.1F48FA00-E1D1-42B2-881C-362A6F549556.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).